Somatic mutation profile of cancer-model specimen HCM-BROD-0198-C71-85B (Adherent Cell Line, passage 10; aliquot HCM-BROD-0198-C71-85B-01D-A78T-36), derived from the primary tumor of HCMI case HCM-BROD-0198-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.8 years (21,484 days).
Specimen HCM-BROD-0198-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a89f22bd-9f7b-4db5-a8ce-2fd77e1db552.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0198-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0198-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/857d96a2-9c7f-4b28-8d5c-962ba21980dd

The open-access MAF lists 68 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Intron 7, Nonsense Mutation 2, RNA 2, 5'UTR 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 121/122 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs121909239, CM051216, CM159947, COSV64289881, COSV64296805, COSV64297163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2198G>A p.R733Q (on ENST00000372530 / NM_001198934.2; = p.R705Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/202 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150052458; called by muse, mutect2, varscan2
- AKAP9 | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 106/414 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs148726562; called by muse, mutect2, varscan2
- ATP8B4 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs745355532, COSV52708582; called by muse, mutect2, varscan2
- COL11A1 | c.3044G>T p.G1015V | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1343845258, COSV100615753, COSV62178438; called by muse, mutect2, varscan2
- FAT2 | c.2974C>T p.R992* | Nonsense Mutation (SNP) | VAF 176/362 reads (49%) | catalogued as COSV55828350; called by muse, mutect2, varscan2
- FLG | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 182/428 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as rs139207952, COSV100911823; called by muse, mutect2
- HMCN1 | c.13589G>C p.G4530A | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99624428; called by muse, mutect2
- IGHV3-66 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 129/240 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.557); catalogued as rs781857160; called by muse, mutect2, varscan2
- IL2RA | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 146/161 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56919782; called by muse, mutect2, varscan2
- KCP | c.4015C>T p.R1339C (on ENST00000620378; = p.R1463C on NM_001366122.1) | Missense Mutation (SNP) | VAF 119/426 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs748855812; called by muse, mutect2, varscan2
- KRTAP1-3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 226/501 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs775007516; called by muse, mutect2, varscan2
- LAMA5 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53360309; called by muse, mutect2, varscan2
- LPA | c.5794G>A p.V1932I | Missense Mutation (SNP) | VAF 196/410 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as rs761853859; called by muse, mutect2, varscan2
- NKD2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 148/297 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs754988202; called by muse, mutect2, varscan2
- OR10H5 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100454642; called by muse, mutect2
- OR4S1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 89/144 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs371001252, COSV100180378; called by muse, mutect2, varscan2
- PRODH2 | c.887G>A p.R296H (on ENST00000301175; = p.R220H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374055330; called by muse, mutect2, varscan2
- RBPJL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1316863024, COSV100643470; called by muse, mutect2, varscan2
- RYR1 | c.6388G>A p.G2130R | Missense Mutation (SNP) | VAF 101/523 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs193922789, CM077969; ClinVar: not provided; called by muse, mutect2, varscan2
- SLC35G3 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 396/801 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs765407465, COSV52012930; called by muse, mutect2, varscan2
- SOBP | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433222; called by muse, mutect2, varscan2
- SYT7 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1285369099; called by muse, mutect2, varscan2
- TICAM1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373468408, COSV99941051; called by muse, mutect2, varscan2
- ZIC2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 359/752 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66255530; called by muse, mutect2, varscan2
- ZNF500 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 119/250 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1449140005; called by muse, mutect2, varscan2
- AURKA | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BBS9 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCS1L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 71/158 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC168 | c.19619A>G p.N6540S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNOT1 | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- DGCR8 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 131/261 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GGA3 | c.1352C>A p.A451D (on ENST00000537686 / NM_138619.4; = p.A418D on NM_014001.5) | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- JAG1 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD5 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); called by muse, mutect2
- OCIAD1 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PODNL1 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 136/405 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RAB6C | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STAB2 | c.5155A>G p.I1719V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by mutect2, varscan2
- STT3B | c.490_491del p.V164Sfs*14 | Frame Shift Del (DEL) | VAF 68/175 reads (39%) | called by mutect2, pindel, varscan2
- ZNF142 | c.2959C>T p.P987S (on ENST00000411696 / NM_001379660.1; = p.P787S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF814 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZSCAN1 | c.916C>A p.H306N | Missense Mutation (SNP) | VAF 246/475 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACSL6 | c.1473C>A p.L491= (on ENST00000379240; = p.L516= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/181 reads (44%) | catalogued as COSV57297186, COSV57299406; called by muse, mutect2, varscan2
- BEST3 | c.1386G>A p.L462= | Silent (SNP) | VAF 125/258 reads (48%) | called by muse, mutect2, varscan2
- CHST1 | c.708C>T p.P236= | Silent (SNP) | VAF 52/236 reads (22%) | called by muse, mutect2, varscan2
- FSTL4 | c.291C>T p.Y97= | Silent (SNP) | VAF 221/461 reads (48%) | catalogued as rs762313986, COSV54772363; called by muse, mutect2, varscan2
- GPR4 | c.922C>T p.L308= | Silent (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- H1-6 | c.288C>T p.I96= | Silent (SNP) | VAF 241/457 reads (53%) | catalogued as rs776785708; called by muse, mutect2, varscan2
- MS4A8 | c.312C>T p.Y104= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as rs144254483, COSV55753762; called by muse, mutect2, varscan2
- PCDHA5 | c.1350C>T p.N450= | Silent (SNP) | VAF 290/594 reads (49%) | catalogued as rs61730629, COSV65348992; called by muse, mutect2, varscan2
- PRLHR | c.657G>A p.E219= | Silent (SNP) | VAF 48/48 reads (100%) | called by muse, mutect2, varscan2
- TACR3 | c.750C>T p.I250= | Silent (SNP) | VAF 63/143 reads (44%) | catalogued as rs1006068692, COSV100510643; called by muse, mutect2, varscan2
- TROAP | c.93T>A p.P31= | Silent (SNP) | VAF 130/302 reads (43%) | called by muse, mutect2, varscan2
- UMODL1 | c.1845C>T p.G615= | Silent (SNP) | VAF 153/300 reads (51%) | catalogued as rs1388927822; called by muse, mutect2, varscan2
- USP43 | c.852G>A p.L284= | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as rs1312679516; called by muse, mutect2, varscan2
- VRK1 | c.690C>T p.I230= | Silent (SNP) | VAF 138/326 reads (42%) | catalogued as rs747694940; ClinVar: likely benign; called by muse, mutect2
- AC136628.2 | n.90C>G | RNA (SNP) | VAF 6/44 reads (14%) | catalogued as rs28517507; called by muse, mutect2
- ECM1 | c.224-51A>C | Intron (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- FCRL6 | c.-20G>A | 5'UTR (SNP) | VAF 81/182 reads (45%) | catalogued as rs371412089; called by muse, mutect2, varscan2
- GALNT13 | c.1396-760C>T | Intron (SNP) | VAF 16/39 reads (41%) | catalogued as rs1485205423; called by muse, mutect2, varscan2
- GOLGA8S | c.348+25G>A | Intron (SNP) | VAF 60/302 reads (20%) | catalogued as rs1330179118; called by muse, mutect2, varscan2
- LAMC2 | c.3070-26G>A | Intron (SNP) | VAF 165/360 reads (46%) | catalogued as rs746973333; called by muse, mutect2, varscan2
- SV2C | c.581-21241G>A | Intron (SNP) | VAF 130/279 reads (47%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.135C>T | RNA (SNP) | VAF 224/503 reads (45%) | catalogued as rs780992440; called by muse, mutect2, varscan2
- TEKT2 | c.283-15C>T | Intron (SNP) | VAF 157/370 reads (42%) | catalogued as rs766262806; called by muse, mutect2, varscan2
- WRAP53 | c.1165-13T>A | Intron (SNP) | VAF 92/501 reads (18%) | called by muse, mutect2, varscan2
